Somatic mutation profile of tumor specimen TCGA-FG-6691-01A (aliquot TCGA-FG-6691-01A-11D-1893-08) from TCGA case TCGA-FG-6691, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 23.0 years (8,403 days).
Specimen TCGA-FG-6691-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ab8bda0-7d2b-4c7b-ba51-93c7d897dfe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-6691-10A (Blood Derived Normal), aliquot TCGA-FG-6691-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29b010d5-cc5d-4afd-a927-70019ffdf34b

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.481_486del p.A161_I162del | In Frame Del (DEL) | VAF 36/61 reads (59%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- DYNC2LI1 | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV53183107; called by muse, mutect2
- GALNT17 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61157415; called by muse, mutect2
- HIVEP3 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs765686223, COSV56013597; called by muse, mutect2, varscan2
- LONRF1 | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68036435; called by muse, mutect2, varscan2
- VIT | c.1220C>T p.T407M (on ENST00000389975 / NM_001177969.1; = p.T422M on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773000051, COSV64896195; called by muse, mutect2, varscan2
- ATRX | c.1074dup p.L359Tfs*3 | Frame Shift Ins (INS) | VAF 48/136 reads (35%) | called by mutect2, varscan2
- IGHV2-26 | c.228C>T p.D76= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs376866206; called by muse, mutect2, varscan2
